Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3433, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3433-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right Renal Mass

Source of Specimen(s):

A: Right kidney

B: Lymph Node, inter aortal

Gross Description:

Received in two parts.

Source of Tissue: 1. Labeled #1, "right kidney"

Frozen Section Diagnosis: 1FS- ONCOCYTIC NEOPLASM PER

Gross Description: Received fresh in a container labeled with the patient's name designated "right kidney". It consists of a 450 gram right nephrectomy specimen measuring 15 x 8 x 9 cm. The ureter measures 10 x 0.5 cm and is normal appearing. Vascular margins are normal appearing. A small amount of perinephric fat contains no suspicious lesions or masses or lymph nodes present. There is a large bulging mass in the inferior pole. Sections disclose a large 9 x 8 x 8 cm tumor obliterating the lower half of the kidney. The tumor pushes on the capsule, however no gross invasion is noted. The tumor is predominantly brownish with some areas of hemorrhage. There is a marked delineation between the tumor and normal adjacent parenchyma. Representative section of tumor was selected for frozen section consultation in 1FS. Representative sections are submitted 1A- vascular ureter margin, 1B- tumor in relationship to capsule, 1C- tumor, 1D- tumor in relationship to adjacent kidney, 1E- uninvolved superior pole kidney, 1F- fat overlying kidney, 1G- hilum

Note: Cytogenetics Sample was Procured.

Source of Tissue: 2. Labeled #2, "inter aortal lymph node" /

Gross Description: Received fresh in a container labeled with the patient's name designated "inter aortal lymph node". It consists of a single rubbery nodule measuring 1.4 x 1.0 x 0.7 cm. It is submitted as is in toto in 2A.

Final Diagnosis:

1. Kidney, right (nephrectomy):

[page 2 of 2]
- Renal cell carcinoma, chromophobe type (9.0 cm gross measurement) arising in the inferior renal pole and confined to the kidney.
- Circumferential, ureteral and vascular margins are negative for tumor.

Note: Immunohistochemical stains show that the tumor cells are diffusely positive for CK7 and E-cadherin (membranous staining), with membranous staining for C-Kit, some areas are positive for CD10; negative for vimentin. Hale's colloidal iron stain is focally positive. Although the areas of CD10 positivity is somewhat unusual, overall, the findings support a diagnosis of chromophobic carcinoma. A cytogenetic study is pending.

2. Inter-aortal lymph node (resection):

- Three lymph nodes negative for tumor (0/3).

(pT2N0Mx).

These tests were developed and their performance characteristics determined by the immunohistochemistry laboratory at the [REDACTED]. These tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement [REDACTED] (CLIA) as qualified to perform high complexity clinical testing.

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Oncocytic neoplasm

KARYOTYPE: Specimen inadequate for cytogenetic analysis.

RESULTS: The renal mass was sent to a commercial laboratory for cytogenetic analysis. The cells failed to grow in culture, and therefore, the analysis could not be performed

Source: NCI Genomic Data Commons file 55782b9a-21f5-49cb-96ab-df4a3934a3f9 (TCGA-AK-3433.60318EBC-051C-4587-82BC-8DF91F8EDF53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).